MMRF case MMRF_1847 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/94e666dd-1748-4f6f-bdad-a7a1bc497466

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.1 years (19,033 days); ISS stage: I; Days to last known disease status: 1,085 days (3.0 years); Days to last follow up: 1,085 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 44 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 20 days; Days to treatment end: 44 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 44 days; Days to treatment end: 128 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 161 days; Days to treatment end: 161 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 380 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 380 days (1.0 years); Days to treatment end: 455 days (1.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 455 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12: M Protein 5.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.662 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.22 mg/dL; Immunoglobulin G 70.3 g/L; Immunoglobulin A 0.141 g/L; Immunoglobulin M 0.265 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 7.07 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 10.9 g/dL; Glucose 4.84 mmol/L.
- Day 128 (ECOG 0): M Protein 0.526 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.8 g/L; Beta 2 Microglobulin 1.3 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 5.01 mmol/L.
- Day 264 (ECOG 1): M Protein 0.0355 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.285 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.84 g/L; Hemoglobin 9.73 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 3.19 mmol/L.
- Day 364 (ECOG 1): M Protein 0.0781 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.672 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 9.42 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 47 g/L; Total Protein 7.1 g/dL; Glucose 4.35 mmol/L.
- Day 455 (ECOG 0): M Protein 0.063 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.745 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 9.36 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 4.9 mmol/L.
- Day 513: Hemoglobin 9.61 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 135 ×10⁹/L.
- Day 553 (ECOG 0): M Protein 0.0195 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.781 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.875 mg/dL; Immunoglobulin G 9.83 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 9.36 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 4.07 mmol/L.
- Day 672 (ECOG 0): Hemoglobin 9.49 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 144 ×10⁹/L.
- Day 798 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 9.18 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 4.68 mmol/L.
- Day 896 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.716 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 8.87 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.61 mmol/L.
- Day 987 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.912 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 9.64 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 0.59 g/L; Hemoglobin 9.36 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 6.16 mmol/L.
- Day 1,085 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.968 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.872 mg/dL; Immunoglobulin G 9.02 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 9.36 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.

Other clinical attributes
- Day -12: Weight: 76 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Melanoma.

Biospecimens (2 samples)
- Sample MMRF_1847_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1847_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
